Surgical pathology report (de-identified scan), TCGA case TCGA-D7-8579, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-8579-01A (Primary Tumor).

Material:

1) Material: stomach, stomach with the tumour. Method of collection: Total organ resection

Histopathological diagnosis:

Examination performed on:

Stomach adenocarcinoma, sold, partly tubular and mucinous. Metastases to 4/14 lymph nodes. (G2, pT2, pN2).

Macroscopic description:

The specimen containing the stomach, after being incised along the greater curvature sized 18 x 19cm with a piece of the omentum sized 15 x 7cm. Wall thickening in the pyloric region over the area of 4.4 x 5.4cm. Distance from the proximal end: 8.8cm, from distal end: 2.6cm.

Microscopic description:

Gastric adenocarcinoma, sold, partly tubular and mucous. (G2, mixed type acc. to Laurena). Invasion in the muscular membrane of the lesser omentum. Vessels affected with embolism Incision lines free of neoplastic lesions. Outside the tumour, signs of chronic high intensity inflammation (+++) with low-intensity foci (+). Lymph nodes: periorificial (L) Sinus histiocytosis (5 nodes) of the lesser curvature (M,N): Metastases to 4/6 lymph nodes, of the greater curvature (P). Sinus histiocytosis (3 nodes)

Assistant:

Pathologist:

HER2 protein stained with Ventana's Pathway HER-2/neu (4B5) Rabbit Monoclonal Antibody.

Positive reaction in invasive cancerous cells (Score = 3+)

Assistant:

Pathologist:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file dcf6c3e8-d243-444e-9d9b-057f06b8bb40 (TCGA-D7-8579.5AB6FC71-A8F0-4AF8-AA62-9F874CF7EC2E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).